Somatic mutation profile of tumor specimen 0DJ4C0 from CCDI case PBBWKJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 11.4 years (4,170 days).
Specimen 0DJ4C0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc182f8c-52c8-4950-b259-3d657a448cf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ4CA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a38a760c-1a21-418f-baf8-4cdc8b208bb6

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDC | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 306/825 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261689439, COSV100779128; called by muse, mutect2, varscan2
- M1AP | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 44/614 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs753905899; called by muse, mutect2
- SLC7A4 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762656597; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 45/1065 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- ELK1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 159/368 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 56/1423 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- SLIT2 | c.430A>C p.R144= | Silent (SNP) | VAF 36/1542 reads (2%) | called by muse, mutect2
- XKR3 | c.519C>T p.L173= | Silent (SNP) | VAF 402/1078 reads (37%) | catalogued as rs754622915, COSV58888047; called by muse, mutect2, varscan2
- ATF6B | c.832+44G>T | Intron (SNP) | VAF 23/284 reads (8%) | catalogued as rs764446128; called by muse, mutect2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 16/162 reads (10%) | catalogued as COSV99987084; called by muse, varscan2
- SSPOP | n.7738G>A | RNA (SNP) | VAF 32/648 reads (5%) | called by muse, mutect2
